Somatic mutation profile of tumor specimen ALCH-B2RF-TTP1-A (aliquot ALCH-B2RF-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2RF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.8 years (26,239 days).
Specimen ALCH-B2RF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e2ebde0-627a-4f75-b856-c2df15ae889a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2RF-NB1-A (Blood Derived Normal), aliquot ALCH-B2RF-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b30da8b4-b088-4cb6-9985-4f9d17b0eb28

The open-access MAF lists 277 somatic variants for this specimen: 175 protein-altering or splice-affecting, 71 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 154, Silent 71, Intron 18, Splice Site 8, Nonsense Mutation 6, Frame Shift Del 5, RNA 4, 5'Flank 4, 3'Flank 2, 3'UTR 2, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 19/126 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC8 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56858124; called by muse, mutect2
- ACTN2 | c.2438C>T p.S813F | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs762914906; called by muse, mutect2, varscan2
- ADCY1 | c.3283G>A p.V1095I | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.006); catalogued as rs763670732, COSV52041109; called by mutect2, varscan2
- AHNAK2 | c.3839C>T p.A1280V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1278884788; called by muse, mutect2, varscan2
- ASXL3 | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs770530147; called by muse, mutect2, varscan2
- ATP2B3 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs782078554, COSV54847673; called by muse, mutect2, varscan2
- BCOR | c.4173+2T>A p.X1391_splice (on ENST00000378444 / NM_001123385.2; = p.X1357_splice on NM_017745.6) | Splice Site (SNP) | VAF 11/123 reads (9%) | catalogued as COSV100654191, COSV60706913; called by muse, mutect2
- CACNA1E | c.6559G>A p.D2187N (on ENST00000367573 / NM_001205293.3; = p.D2144N on NM_000721.4) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1016623006; called by muse, varscan2
- CACNG7 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV55814167; called by muse, mutect2, varscan2
- CENPU | c.480A>T p.Q160H | Missense Mutation (SNP) | VAF 21/333 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV55657413; called by muse, mutect2
- CMYA5 | c.320G>A p.C107Y | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1267160128; called by muse, mutect2, varscan2
- CNR1 | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62986730, COSV62989184; called by muse, mutect2
- COL15A1 | c.2308G>T p.G770* | Nonsense Mutation (SNP) | VAF 11/95 reads (12%) | catalogued as COSV100897296; called by muse, mutect2, varscan2
- CPA6 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV52721363; called by muse, mutect2, varscan2
- CSMD1 | c.2658C>A p.H886Q (on ENST00000520002; = p.H885Q on NM_033225.6) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.812); catalogued as rs377409143, COSV100150660; called by muse, mutect2, varscan2
- DCAF1 | c.3130C>T p.R1044W | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs1434874709; called by muse, mutect2, varscan2
- DIAPH1 | c.3318G>T p.M1106I | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV53880820; called by muse, mutect2, varscan2
- DNAH9 | c.9593C>A p.P3198H | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99306991; called by muse, mutect2
- EEFSEC | c.1169A>G p.D390G | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99631048; called by muse, mutect2, varscan2
- ELOVL4 | c.457C>A p.Q153K | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100876130, COSV100876381; called by muse, mutect2, varscan2
- EMSY | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV58258376; called by muse, mutect2
- EP300 | c.4561G>A p.E1521K | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV54337524, COSV99610420; called by muse, mutect2
- EZH1 | c.1870G>T p.G624* | Nonsense Mutation (SNP) | VAF 12/136 reads (9%) | catalogued as COSV101331378; called by muse, mutect2
- FAM47C | c.2923G>T p.G975C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs782174637, COSV63725649, COSV63727772; called by muse, mutect2, varscan2
- FBN3 | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as COSV99559525; called by muse, mutect2
- FMR1 | c.1565G>T p.R522M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV99502992; called by muse, mutect2, varscan2
- GATA6 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770251106; called by mutect2, varscan2
- GATAD2A | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1296839596, COSV53066981, COSV53075761; called by muse, mutect2
- HMGN5 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.307); catalogued as COSV63917720; called by muse, mutect2
- HSD17B4 | c.1694C>T p.S565F (on ENST00000414835 / NM_001199291.3; = p.S540F on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/251 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs770365591; called by muse, mutect2
- IFT88 | c.1786C>G p.Q596E (on ENST00000319980 / NM_001318493.2; = p.Q587E on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV60676911; called by muse, mutect2
- INSL4 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.041); catalogued as rs370811246; called by muse, mutect2, varscan2
- KIF2B | c.591C>G p.H197Q | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV52126974; called by muse, mutect2
- LPL | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV60931840; called by muse, mutect2
- LRP1B | c.11419G>A p.D3807N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV67237629; called by muse, mutect2, varscan2
- MARCO | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 24/184 reads (13%) | catalogued as rs770063533, COSV59052015; called by muse, mutect2, varscan2
- MTCL1 | c.2552C>T p.P851L (on ENST00000306329 / NM_001378206.1; = p.P491L on NM_015210.4) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs139950675; called by mutect2, varscan2
- NAV3 | c.5618C>A p.T1873N (on ENST00000397909 / NM_001024383.2; = p.T1851N on NM_014903.6) | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.312); catalogued as COSV57067838; called by muse, varscan2
- PARG | c.2273G>A p.R758H | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554835246, COSV67858902; called by muse, mutect2
- PCDH15 | c.1351G>C p.V451L | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.224); catalogued as COSV57328069; called by muse, mutect2
- PCDHB6 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.165); catalogued as COSV50694438; called by muse, mutect2, varscan2
- POLR3B | c.1367C>G p.S456C | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as COSV99943450; called by muse, mutect2, varscan2
- PTPRH | c.706C>A p.P236T | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as rs752959179; called by muse, mutect2, varscan2
- PYGL | c.2380-1G>T p.X794_splice | Splice Site (SNP) | VAF 10/124 reads (8%) | catalogued as COSV53585734; called by muse, mutect2
- RAB10 | c.124A>G p.I42V | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV53091315; called by muse, mutect2, varscan2
- SLITRK1 | c.1751G>T p.R584M | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as CM066602; called by muse, mutect2
- SMARCA4 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV60786460; called by muse, mutect2
- SPATA31A6 | c.869C>A p.S290* | Nonsense Mutation (SNP) | VAF 22/466 reads (5%) | catalogued as COSV100253281, COSV99081771; called by muse, mutect2
- TAF7L | c.261G>A p.M87I | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100229680, COSV61256977; called by muse, mutect2, varscan2
- TBX22 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64788150; called by muse, mutect2
- TBX5 | c.119C>G p.S40W | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs903933027, COSV59858488; called by muse, mutect2
- TOPORS | c.2749G>T p.D917Y | Missense Mutation (SNP) | VAF 15/351 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV62118583; called by muse, mutect2
- VASN | c.236A>G p.Q79R | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as rs760428023; called by muse, mutect2, varscan2
- WIPF2 | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV60276130; called by muse, mutect2
- ZNF536 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs572216856, COSV100835448; called by mutect2, varscan2
- ZNF99 | c.1143G>T p.L381F | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs539751305, COSV68056039; called by muse, mutect2, varscan2
- ZSCAN18 | c.247C>A p.R83S | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.738); catalogued as COSV53735082; called by muse, mutect2
- ABCC11 | c.1945T>C p.Y649H | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSM5 | c.1586C>A p.P529Q | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.043); called by muse, mutect2
- ADAM10 | c.895A>T p.K299* | Nonsense Mutation (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- ADAM17 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADGRB3 | c.3076G>T p.V1026L | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADGRG4 | c.7372C>A p.L2458I | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.379); called by muse, mutect2
- ADGRG6 | c.3538A>T p.S1180C | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2
- AFF2 | c.2840G>C p.G947A | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.192); called by muse, mutect2
- AHNAK | c.16780G>T p.G5594W | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF10L | c.689G>C p.R230T | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.171); called by muse, mutect2
- ASXL1 | c.3962A>T p.D1321V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2
- BARX1 | c.599T>C p.I200T | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- BCLAF3 | c.940C>G p.Q314E | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.318); called by muse, mutect2
- BIRC6 | c.4244del p.G1415Afs*15 | Frame Shift Del (DEL) | VAF 12/102 reads (12%) | called by mutect2, varscan2
- BLM | c.338A>G p.Q113R | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- BLM | c.797G>C p.R266T | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.351); called by muse, mutect2
- BRAT1 | c.1084G>T p.A362S | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.319); called by muse, mutect2
- C3orf33 | c.199G>T p.D67Y (on ENST00000340171 / NM_001308229.2; = p.D24Y on NM_173657.2) | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- C6orf118 | c.779G>T p.S260I | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); called by muse, mutect2
- CASR | c.2664G>T p.K888N (on ENST00000490131; = p.K965N on NM_000388.4) | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- CDH6 | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDK18 | c.1189G>T p.G397C (on ENST00000506784 / NM_212503.3; = p.G367C on NM_002596.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CFHR1 | c.253+3G>A | Splice Region (SNP) | VAF 16/220 reads (7%) | called by muse, mutect2
- COL5A2 | c.4353+1G>T p.X1451_splice | Splice Site (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- COL6A2 | c.1412C>A p.P471H | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.405); called by muse, mutect2
- CR1 | c.3127G>A p.A1043T | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.028); called by muse, mutect2
- CSF2RB | c.2039G>T p.G680V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.113); called by muse, mutect2
- DCAF15 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- DCDC2C | c.688T>C p.Y230H | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- DLX5 | c.679C>A p.Q227K | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.045); called by muse, mutect2
- DNAH8 | c.5881G>C p.E1961Q | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DYNC2I1 | c.1798G>T p.A600S | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2
- EFEMP1 | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- EIF4A3 | c.125C>A p.T42N | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- EML5 | c.4063A>G p.K1355E (on ENST00000380664; = p.K1363E on NM_183387.3) | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.1); called by muse, mutect2
- EPB42 | c.1405C>A p.L469I (on ENST00000441366 / NM_001114134.2; = p.L499I on NM_000119.3) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.053); called by muse, mutect2
- ERI3 | c.759-1G>T p.X253_splice | Splice Site (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- ERN1 | c.1861dup p.E621Gfs*128 | Frame Shift Ins (INS) | VAF 13/92 reads (14%) | called by mutect2, pindel, varscan2
- EVI5L | c.523G>T p.G175C | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM71F2 | c.500G>T p.W167L | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAT2 | c.1987C>T p.H663Y | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2
- FCHO1 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FLG | c.4379C>A p.P1460H | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.395); called by muse, mutect2
- FLRT1 | c.160T>A p.C54S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FLT1 | c.849C>A p.D283E | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- FXR1 | c.1834C>G p.Q612E | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2
- GLRA4 | c.494+1G>T p.X165_splice | Splice Site (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- GLRA4 | c.494G>T p.R165M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPRASP1 | c.1731G>C p.E577D | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GRIK1 | c.2427G>A p.M809I | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.417); called by muse, mutect2
- GZMK | c.549C>G p.S183R | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.319); called by muse, mutect2
- HOXD11 | c.37A>C p.S13R | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- IL1RAPL1 | c.1454G>T p.R485M | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- INPP4B | c.2479G>T p.A827S | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.791); called by muse, mutect2
- ITGA3 | c.3125C>T p.S1042L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- KAT14 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- KCNJ8 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- KIAA1210 | c.3903G>C p.L1301F | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- KIF11 | c.2938G>C p.E980Q | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.305); called by muse, mutect2
- KIR3DL2 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LMNTD1 | c.953G>T p.R318I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LRP1B | c.11884G>A p.G3962S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- LRP5 | c.4130C>T p.S1377L | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- LZTS1 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCC | c.1047del p.E350Kfs*5 | Frame Shift Del (DEL) | VAF 15/124 reads (12%) | called by mutect2, pindel, varscan2
- MRO | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- MRTFB | c.1636A>G p.M546V | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MUC2 | c.3647C>T p.S1216F | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.335); called by muse, mutect2
- MYOM2 | c.3470A>G p.K1157R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- NAA10 | c.520G>T p.G174C | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2
- NHLRC3 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); called by muse, mutect2
- NLRP14 | c.2358G>T p.Q786H | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.037); called by muse, mutect2
- NONO | c.1109_1128del p.F370Cfs*57 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- NRAP | c.3798C>A p.N1266K (on ENST00000359988 / NM_001322945.2; = p.N1231K on NM_006175.4) | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- NTSR2 | c.121C>G p.L41V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.175); called by muse, varscan2
- NUAK2 | c.484G>C p.A162P | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDE10A | c.1754T>A p.L585H | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE10A | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); called by muse, varscan2
- PDE6C | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- PDZD4 | c.10A>G p.N4D | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- PIP4P2 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- PLEKHB2 | c.344del p.G115Afs*5 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- PLEKHG4B | c.220G>T p.G74W (on ENST00000283426; = p.G430W on NM_052909.5) | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- PLXNA3 | c.3332C>A p.A1111D | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2
- PLXNC1 | c.2150C>A p.T717N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, varscan2
- POTEE | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 25/338 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- POTEJ | c.2226G>T p.W742C | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PSMD10 | c.388del p.A130Lfs*23 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- PTPRF | c.726G>C p.E242D | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); called by muse, mutect2
- RET | c.3236G>C p.R1079T | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RHBDD3 | c.812C>G p.S271* | Nonsense Mutation (SNP) | VAF 9/147 reads (6%) | called by muse, mutect2
- RIMS2 | c.1030G>T p.V344L (on ENST00000666250 / NM_001348490.2; = p.V152L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RIOK2 | c.199A>G p.T67A | Missense Mutation (SNP) | VAF 20/366 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2
- SELENON | c.404G>T p.R135M | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.803); called by muse, mutect2
- SLC38A2 | c.1180-1G>T p.X394_splice | Splice Site (SNP) | VAF 21/153 reads (14%) | called by muse, mutect2, varscan2
- SLC4A3 | c.1841C>T p.S614F | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- SNRPE | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2
- SPON1 | c.1150C>A p.H384N | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.401); called by muse, mutect2
- SUZ12 | c.158C>G p.S53W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.984); called by muse, mutect2
- SYN1 | c.774+1G>A p.X258_splice | Splice Site (SNP) | VAF 20/292 reads (7%) | called by muse, mutect2
- TAOK3 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TECRL | c.658-2A>T p.X220_splice | Splice Site (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- THSD1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNS1 | c.3654G>T p.M1218I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TPO | c.738G>T p.Q246H | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIP11 | c.4438C>G p.Q1480E | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.067); called by muse, mutect2
- TRRAP | c.6570C>G p.F2190L (on ENST00000359863 / NM_001244580.1; = p.F2172L on NM_003496.3) | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2
- TSPAN19 | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- TTLL6 | c.1948C>T p.L650F (on ENST00000393382 / NM_001130918.3; = p.L343F on NM_173623.3) | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- VPS39 | c.2321T>G p.V774G (on ENST00000348544 / NM_001301138.2; = p.V763G on NM_015289.5) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- WDR13 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZFHX4 | c.5485C>A p.Q1829K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZFP64 | c.618G>C p.K206N | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ZNF383 | c.206G>C p.R69T | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.118); called by muse, mutect2
- ZNF619 | c.1336G>T p.G446W | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF700 | c.29G>C p.R10T | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.227); called by muse, mutect2
- ZNF711 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); called by muse, mutect2
- ADGRF2 | c.1248C>A p.S416= (on ENST00000296862 / NM_001368115.2; = p.S348= on NM_153839.7) | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV57289295; called by muse, mutect2, varscan2
- ANG | c.159C>T p.I53= | Silent (SNP) | VAF 24/298 reads (8%) | called by muse, mutect2
- APLNR | c.324C>T p.L108= | Silent (SNP) | VAF 13/137 reads (9%) | called by muse, mutect2
- ARHGAP35 | c.4014G>A p.Q1338= | Silent (SNP) | VAF 9/118 reads (8%) | called by muse, mutect2
- BECN1 | c.408C>G p.L136= | Silent (SNP) | VAF 9/205 reads (4%) | called by muse, mutect2
- BTLA | c.312A>G p.P104= | Silent (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2
- C5orf38 | c.372G>A p.L124= | Silent (SNP) | VAF 13/137 reads (9%) | called by muse, mutect2
- CCR1 | c.228G>T p.L76= | Silent (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- CELA2B | c.462C>T p.P154= | Silent (SNP) | VAF 6/109 reads (6%) | catalogued as COSV65546051; called by muse, mutect2
- CLN8 | c.33G>A p.E11= | Silent (SNP) | VAF 7/109 reads (6%) | called by muse, mutect2
- CSMD1 | c.1107T>A p.G369= (on ENST00000520002; = p.G368= on NM_033225.6) | Silent (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- CWH43 | c.1956T>C p.Y652= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as rs1315873351; called by muse, mutect2
- CX3CR1 | c.444C>T p.T148= | Silent (SNP) | VAF 23/136 reads (17%) | called by muse, mutect2, varscan2
- DCAF17 | c.714C>T p.F238= | Silent (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- DDX42 | c.1122G>A p.Q374= | Silent (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- DLGAP4 | c.1084C>A p.R362= | Silent (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- DNAH9 | c.9594C>A p.P3198= | Silent (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- EPB41L2 | c.621A>T p.A207= | Silent (SNP) | VAF 14/326 reads (4%) | called by muse, mutect2
- ERBB2 | c.774C>T p.F258= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV54078623; called by muse, mutect2
- FANCA | c.1098G>C p.L366= | Silent (SNP) | VAF 31/324 reads (10%) | catalogued as COSV66881457, COSV66883819; called by muse, mutect2, varscan2
- FBXO30 | c.390G>A p.R130= | Silent (SNP) | VAF 18/244 reads (7%) | catalogued as rs201737062; called by muse, mutect2
- FER1L5 | c.2436C>A p.T812= (on ENST00000623019; = p.T817= on NM_001293083.2) | Silent (SNP) | VAF 15/72 reads (21%) | called by muse, varscan2
- FYTTD1 | c.510A>T p.P170= | Silent (SNP) | VAF 9/149 reads (6%) | called by muse, mutect2
- GALNT3 | c.1374A>T p.A458= | Silent (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- GAS6 | c.1164G>T p.A388= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs375788560; called by mutect2, varscan2
- GRIA3 | c.1359C>A p.G453= | Silent (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2, varscan2
- GRIPAP1 | c.2262C>A p.V754= | Silent (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- HERC1 | c.2667C>T p.I889= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs770420486; called by muse, mutect2, varscan2
- HTR3D | c.1035C>A p.L345= (on ENST00000382489 / NM_001163646.2; = p.L170= on NM_182537.3) | Silent (SNP) | VAF 28/239 reads (12%) | called by muse, mutect2, varscan2
- IGKV1-8 | c.150C>T p.S50= | Silent (SNP) | VAF 18/194 reads (9%) | catalogued as rs577716550; called by muse, mutect2
- IGKV1D-43 | c.81C>G p.T27= | Silent (SNP) | VAF 12/198 reads (6%) | catalogued as rs1334165624; called by muse, mutect2
- IL18R1 | c.336C>T p.I112= | Silent (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- JPH3 | c.1269C>T p.F423= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2, varscan2
- KPNA6 | c.1206C>T p.I402= | Silent (SNP) | VAF 15/185 reads (8%) | called by muse, mutect2
- MAPKBP1 | c.2817G>A p.G939= (on ENST00000456763 / NM_001128608.2; = p.G933= on NM_014994.3) | Silent (SNP) | VAF 13/202 reads (6%) | called by muse, mutect2
- MKNK2 | c.99C>T p.H33= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs1296267578; called by muse, varscan2
- MOCOS | c.2592G>T p.V864= | Silent (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- MTRES1 | c.193C>T p.L65= | Silent (SNP) | VAF 16/346 reads (5%) | catalogued as rs1554227436; called by muse, mutect2
- NAV3 | c.5619C>A p.T1873= (on ENST00000397909 / NM_001024383.2; = p.T1851= on NM_014903.6) | Silent (SNP) | VAF 15/151 reads (10%) | called by muse, varscan2
- NCOA7 | c.600G>A p.L200= | Silent (SNP) | VAF 12/213 reads (6%) | catalogued as COSV57654402; called by muse, mutect2
- NOTCH2 | c.5037C>T p.L1679= | Silent (SNP) | VAF 27/304 reads (9%) | called by muse, mutect2
- NOXA1 | c.555G>T p.R185= | Silent (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- NR4A2 | c.33G>T p.S11= | Silent (SNP) | VAF 15/174 reads (9%) | catalogued as COSV100276976; called by muse, mutect2, varscan2
- OCA2 | c.1380C>T p.L460= | Silent (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- OR2M7 | c.621T>A p.L207= | Silent (SNP) | VAF 30/275 reads (11%) | called by muse, mutect2, varscan2
- OR2T11 | c.444G>C p.G148= | Silent (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2
- OR51L1 | c.384C>T p.I128= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV58624935; called by muse, mutect2
- PASD1 | c.540C>A p.L180= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100949321; called by muse, mutect2
- PDCD1 | c.547C>T p.L183= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as rs956372956; called by muse, mutect2
- PFKFB4 | c.1332G>T p.T444= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as rs1005360359; called by muse, mutect2
- PIGT | c.1521G>T p.R507= | Silent (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- PMS1 | c.1437G>A p.G479= | Silent (SNP) | VAF 20/287 reads (7%) | called by muse, mutect2
- ROR2 | c.300C>T p.A100= | Silent (SNP) | VAF 15/208 reads (7%) | called by muse, mutect2
- SAG | c.1071C>T p.F357= | Silent (SNP) | VAF 22/217 reads (10%) | called by muse, mutect2, varscan2
- SDK1 | c.1770G>C p.T590= | Silent (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2, varscan2
- SEMA3B | c.1872C>A p.R624= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, varscan2
- SFMBT1 | c.1665C>T p.V555= | Silent (SNP) | VAF 19/272 reads (7%) | called by muse, mutect2
- SFTPB | c.561G>A p.A187= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs543913426, COSV60892598; called by muse, mutect2
- SGCG | c.597G>T p.R199= | Silent (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- SI | c.2322G>A p.R774= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as COSV52266138; called by muse, mutect2, varscan2
- SLC15A1 | c.663G>A p.G221= | Silent (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- SMARCC1 | c.1218G>C p.A406= | Silent (SNP) | VAF 27/268 reads (10%) | catalogued as COSV54379035, COSV54384858; called by muse, mutect2
- SYT2 | c.984G>A p.V328= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV66142495; called by muse, mutect2
- TCERG1L | c.720C>A p.I240= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV64054636; called by muse, mutect2, varscan2
- TGIF2LX | c.534C>A p.A178= | Silent (SNP) | VAF 13/267 reads (5%) | called by muse, mutect2
- TMEM135 | c.319C>T p.L107= | Silent (SNP) | VAF 11/186 reads (6%) | catalogued as rs1051985506; called by muse, mutect2
- TRIP13 | c.1194G>T p.L398= | Silent (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2, varscan2
- U2AF1L4 | c.555C>G p.L185= (on ENST00000412391; = p.S127C on NM_144987.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as rs1019608994; called by muse, mutect2
- UNC5B | c.1152C>T p.I384= | Silent (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- XG | c.471A>T p.G157= | Silent (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- ZFYVE21 | c.684C>G p.L228= | Silent (SNP) | VAF 6/62 reads (10%) | called by mutect2, varscan2
- AL353804.4 | chrX:73825984 C>A | 5'Flank (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- AL353804.7 | chrX:73846376 G>T | 5'Flank (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- AMPH | c.1183-1145G>A | Intron (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- ASAP1 | c.60-3592G>C | Intron (SNP) | VAF 19/460 reads (4%) | called by muse, mutect2
- CACNA1C | c.1217+390C>A | Intron (SNP) | VAF 24/164 reads (15%) | catalogued as COSV59702753, COSV59725371; called by muse, mutect2, varscan2
- CCDC138 | chr2:108786765 A>T | 5'Flank (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- HAPLN1 | c.-26-26C>A | Intron (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- IFT74 | c.306-41G>T | Intron (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2
- JAG1 | chr20:10636377 G>A | 3'Flank (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- KCNN1 | c.*1563G>A | 3'UTR (SNP) | VAF 8/71 reads (11%) | catalogued as rs998449260; called by muse, mutect2, varscan2
- KLK4 | c.*33C>A | 3'UTR (SNP) | VAF 12/189 reads (6%) | called by muse, mutect2
- LINC01101 | n.399G>T | RNA (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- LINC01148 | n.502C>A | RNA (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- MBOAT2 | c.76-15787C>G | Intron (SNP) | VAF 10/94 reads (11%) | called by muse, varscan2
- MYH11 | c.2859+35C>A | Intron (SNP) | VAF 15/118 reads (13%) | called by muse, mutect2, varscan2
- NAALADL2 | c.-11G>A | 5'UTR (SNP) | VAF 6/52 reads (12%) | catalogued as COSV101440503; called by muse, mutect2, varscan2
- NCOR2 | c.6959-1496G>T | Intron (SNP) | VAF 30/235 reads (13%) | called by muse, mutect2
- NCOR2 | c.6959-1498A>T | Intron (SNP) | VAF 30/236 reads (13%) | called by muse, mutect2
- NRG3 | c.824-125945G>T | Intron (SNP) | VAF 22/176 reads (13%) | called by muse, mutect2, varscan2
- OR2L1P | n.537G>T | RNA (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- PARP1 | c.2659-17C>G | Intron (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.5187+31A>T | Intron (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158736 G>T | 5'Flank (SNP) | VAF 9/163 reads (6%) | called by muse, mutect2
- SNTN | c.286-194C>A | Intron (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2, varscan2
- STAG3L4 | n.323G>T | RNA (SNP) | VAF 24/281 reads (9%) | called by muse, mutect2
- SYT14 | c.61+444T>A | Intron (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- TESC | c.349+224G>T | Intron (SNP) | VAF 33/252 reads (13%) | called by muse, mutect2, varscan2
- THSD4 | c.1016-70481C>A | Intron (SNP) | VAF 10/111 reads (9%) | catalogued as rs1324743795; called by muse, mutect2, varscan2
- TPD52L3 | chr9:6331020 C>A | 3'Flank (SNP) | VAF 6/50 reads (12%) | called by mutect2, varscan2
- VRK3 | c.612+47C>T | Intron (SNP) | VAF 11/127 reads (9%) | called by muse, mutect2
- ZNF812P | n.544+2392C>A | Intron (SNP) | VAF 11/90 reads (12%) | called by muse, mutect2, varscan2
